Gene-level copy-number profile of tumor specimen TARGET-40-0A4I65-01A from TARGET case TARGET-40-0A4I65, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 17.9 years (6,520 days).
Specimen TARGET-40-0A4I65-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.50f72a8f-7ccc-51db-b8a6-a5dacc064228.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-0A4I65-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 404 have no estimate.
https://portal.gdc.cancer.gov/files/925dbb5d-763b-476b-a685-04682a830f68

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1,072; copy number 1: 740; copy number 2: 11,126; copy number 3: 22,432; copy number 4: 17,690; copy number 5: 2,521; copy number 6: 2,127; copy number 7: 847; copy number 8: 767; copy number 9: 130; copy number 10: 53; copy number 11: 364; copy number 13: 81; copy number 14: 84; copy number 17: 126; copy number 19: 26; copy number 36: 33.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,501 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,274,552–72,275,159, 1 gene, copy number 10: GDI2P2.
- chr1:72,301,472–72,301,829, 1 gene, copy number 10: RPL31P12.
- chr1:164,555,584–164,980,137, 9 genes, copy number 8: PBX1, RNU6-171P, AL391001.1, Metazoa_SRP, PBX1-AS1, AL357568.1, Y_RNA, RPL35AP7, RNU6-755P.
- chr1:165,581,613–178,921,841, 271 genes, copy number 7–8 (broad region; genes not listed).
- chr1:180,632,022–187,686,628, 125 genes, copy number 7–8 (within-gene range 1–8) (broad region; genes not listed).
- chr1:188,013,642–189,666,256, 14 genes, copy number 8: AL136372.2, AL136372.1, RN7SKP156, AL596211.1, AL592447.1, AL929288.1, AL929288.2, RPS3AP9, AL691515.1, AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75, RNA5SP73.
- chr1:198,450,666–205,469,024, 197 genes, copy number 7–8 (within-gene range 1–8) (broad region; genes not listed).
- chr2:121,649,320–124,025,173, 19 genes, copy number 7–9 (within-gene range 6–9): NIFK-AS1, RPL12P15, AC018737.2, NPM1P32, NIFK, TSN, AC018737.1, LINC01823, AC011246.1, AC073632.1, AC062020.1, LINC01826, AC073409.2, AC073409.1, ELOAP1, PSMD14P1, AC064859.1, RN7SKP102, AC079154.1.
- chr4:10,167,159–10,200,672, 2 genes, copy number 7: AC006499.6, AC006499.1.
- chr8:46,028,804–56,993,867, 171 genes, copy number 7–9 (broad region; genes not listed).
- chr8:68,293,446–69,178,189, 10 genes, copy number 7: RPL31P40, C8orf34-AS1, C8orf34, RPS15AP25, RNA5SP269, AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1.
- chr8:72,202,751–78,719,765, 90 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr8:85,440,596–93,744,534, 117 genes, copy number 7 (broad region; genes not listed).
- chr8:105,929,126–141,002,216, 387 genes, copy number 7–8 (broad region; genes not listed).
- chr10:31,602,862–36,089,389, 77 genes, copy number 13–36 (broad region; genes not listed).
- chr13:58,751,047–58,752,233, 1 gene, copy number 9: DNAJA1P1.
- chr13:65,787,932–65,788,764, 1 gene, copy number 7: HNRNPA3P5.
- chr13:71,296,210–73,995,056, 29 genes, copy number 7–13 (within-gene range 2–13): RABEPKP1, DACH1, H3P36, RPL21P109, RPL35AP31, RPS10P21, AL139003.1, RPL18AP17, AL139003.2, AL356754.2, AL356754.1, RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392, KLF12.
- chr13:73,844,683–75,136,940, 12 genes, copy number 7–8: AL159972.1, LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1, RNU6-38P, SSR1P2.
- chr13:77,535,674–80,134,368, 41 genes, copy number 7: SCEL, AL137140.1, SCEL-AS1, RNY3P7, SPTLC1P5, AL450447.1, SLAIN1, MIR3665, EDNRB-AS1, EDNRB, OBI1-AS1, AL139002.1, RN7SL810P, LINC01069, LINC00446, AL138957.1, SRGNP1, RNY3P3, RPL31P54, ELOCP23, AL445209.1, POU4F1, OBI1, RPL21P111, LINC00331, HSPD1P8, CCT5P2, NIPA2P5, BCAS2P3, RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, AL136442.1, LINC01038, LINC00382, AL158064.1, LINC01080, AL137781.1.
- chr14:18,333,726–24,657,774, 472 genes, copy number 8–17 (broad region; genes not listed).
- chr17:142,789–979,776, 27 genes, copy number 11 (within-gene range 4–11): DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3, AC141424.1, C17orf97, RFLNB, AC015853.2, VPS53, AC015853.3, AC015853.1, AC027455.1, RPS4XP17, TLCD3A, GEMIN4, DBIL5P, GLOD4, AC087392.3, MRM3, AC087392.4, AC087392.5, NXN, AC087392.2, AC087392.1.
- chr17:11,953,889–18,414,380, 211 genes, copy number 7–13 (broad region; genes not listed).
- chr17:18,476,737–22,606,703, 214 genes, copy number 9–11 (within-gene range 2–11) (broad region; genes not listed).
- chr18:78,036,739–78,140,887, 2 genes, copy number 7: RNU6-655P, AC107892.1.

Autosomal genes at a single copy (total copy number 1): 360. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
